CCDI case PBCWCP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/5d10a131-66ca-4733-aab8-c543a1a87eb9

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1ADG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1AES: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E1AG1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
